Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1Y2, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1Y2-01A (Primary Tumor).

[page 1 of 2]
Department of Cancer Pathology

Date:

Examination: Histopathological examination (cito)

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender: F

Material: Multiple organ resection – right breast with axillary tissues

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination: 5 working days

Clinical diagnosis:

1CD-0-3
carcinoma, infiltrating duct, NOS 8500/3
Site: breast, NOS C50.9 for 4/12/11

Examination performed on:

Macroscopic description:

Right breast, sized 24.8 x 19.3 x 5.2 cm, removed with axillary tissues sized 8.0 x 7.5 x 3.0 cm and a skin flap of 28.6 x 14.6 cm.

Tumour sized 2.2 x 1.7 x 2.4 found in the lower outer quadrant, located 5.2 cm from the lower boundary, 1.7 cm from the base and 0 cm from the skin.

Microscopic description:

Carcinoma ductale invasivum NHG3 (3+3+2: 10 mitoses/10 HPF - visual area 0.55 mm).

Mamillae sine laesionibus.

Glandular tissue showing parenchymal atrophy.

Axillary lymph nodes:

Lymphonodulitis chronica (No VII).

Histopathological diagnosis:

Carcinoma ductale invasivum mammae dextrae. Invasive ductal carcinoma of the right breast. (NHG3, pT2, pN0).

Examination performed on:

Results of immunohistochemical examination:

Estrogen receptors found in over 75% of neoplastic cell nuclei. Progesterone receptors found in less than 10% of neoplastic cell nuclei. HER2 protein stained with Ventana's Pathway HER-2/neu (4B5) rabbit antibody. Score=2+, FISH verification recommended.

[page 2 of 2]
Examination: Histopathological examination (cito)

page 2 / 2

Examination No.:

Patient: XXX

PESEL: XXX

Gender: F

Examination performed on: .

Result of immunohistochemical examination:

RESULT OF HER2/neu GENE AMPLIFICATION with the FISH method by Path Vysion HER2 DNA Probe Kit

FINAL RESULT:

HER-2 GENE AMPLIFICATION NOT FOUND

Compliance validated by:

CONTACT YOUR DOCTOR WITH THIS REPORT

Source: NCI Genomic Data Commons file 8245b3d4-86de-495e-9dd2-ccbde10f0074 (TCGA-D8-A1Y2.4ACD42D6-9520-4DC6-BB40-9187A4D49981.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).